Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A27E, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A27E-01A (Primary Tumor).

1CB-0-3

carcinoma, infiltrating duct and
mucinous 8523/3

Site: breast, NOS C50.9

for 5/19/11

page 1 / 1

Department of Cancer Pathology

copy No. 2

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age: Gender: F

Material: Partial organ resection – left breast, inner upper quadrant.

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: 5 working days

Clinical diagnosis:

Examination performed on:

Macroscopic description:

Part of the breast sized 6.6 x 5.3 x 1.9 cm removed together with a skin flap of 5.8 x 3.3 cm, marked typically, with an X-ray image. Tumour in cross section sized 0.9 x 0.8 x 1.7 cm. Location of margins: 0.4 cm to the base; 0.5 cm to the front surface; 1.8 cm to the sternum; 3.7 cm to the axilla; 1.8 cm to the shoulder 2.3 cm, 1.7 cm to the lower edge.

Radiogram showing a shadowing of 1.4 x 1.4 cm, skin injected with blue dye.

Microscopic description:

Carcinoma ductale invasivum partim mucinosum invasivum mammae sinistrae NHG2 (3 + 2 + 1/1 mitosa/10 HPF, visual area diameter: 0.55 mm). Largest lesion dimension 1.7 cm. Normal tissue margins as in the macroscopic description. Surgical specimen texture outside tumour showing mastopathia fibrosa partim lipomatosis.

Histopathology Diagnosis:

Carcinoma ductale partim mucinosum invasivum mammae sinistrae N1G2, pT1c.

Invasive ductal and in part mucinous carcinoma of the left breast.

dr

Compliance validated by: dr

HPV/A Discrepancy		
Dx-1/Simultaneous Primary		

Source: NCI Genomic Data Commons file c7f66797-5326-4c7b-8821-51fca002352b (TCGA-D8-A27E.36F6CB19-17FE-47FA-BFCA-3846578C028B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).